Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5399, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5399-01A (Primary Tumor).

PATIENT HISTORY:

with a 4 cm well circumscribed right lower pole kidney mass seen on CT.

FINAL DIAGNOSIS:

PARTS ONE AND TWO:

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 2/4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 4.5 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. ALL FINAL ASSESSED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASM.
- G. PATHOLOGIC TNM STAGE: pT1b NX MX (SEE COMMENT AND SYNOPSIS).

COMMENT:

Carcinoma is present at the specimen capsular resection margin (part two). However, additional pericapsular soft tissue (part one) is free of neoplasm. In addition, the inked parenchymal resection margins examined in part one are free of neoplasm. Therefore, the final surgical resection margins are interpreted as free of neoplasm.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE:	Partial nephrectomy
LATERALITY:	Right
TUMOR SITE:	Lower pole
FOCALITY:	Unifocal
TUMOR SIZE:	Greatest dimension: 4.5 cm Additional dimensions: 4.4 x 3.5 cm
MACROSCOPIC EXTENT OF TUMOR:	Tumor limited to kidney
HISTOLOGIC TYPE:	Clear cell (conventional) renal carcinoma
HISTOLOGIC GRADE (Fuhrman Nuclear Grade):	G2
PATHOLOGIC STAGING (pTNM):	pT1b pNX Number of regional lymph nodes examined: 0 pMX
MARGINS:	Margins uninvolved by invasive carcinoma
ADRENAL GLAND:	Not present
LYMPH-VASCULAR INVASION (LVI):	Absent/not identified
ADDITIONAL PATHOLOGIC FINDINGS:	None identified
KIDNEY-RESIDUAL TUMOR (R):	R0

Source: NCI Genomic Data Commons file 3519a807-4bd9-4171-af19-41b9ca969041 (TCGA-B0-5399.92E4DEEE-76FC-4B01-952A-674E35B4CF80.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).